TCGA case TCGA-FL-A1YN — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Primary site: Uterus, NOS; Tissue source site: University of Hawaii - Normal Study.
https://portal.gdc.cancer.gov/cases/d72264ec-d4d7-423a-9216-ae4485f81aba

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FL-A1YN-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 60 mg.
  Slide TCGA-FL-A1YN-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent normal cells: 100.
